Surgical pathology report (de-identified scan), TCGA case TCGA-JY-A6FB, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University Health Network, specimen TCGA-JY-A6FB-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: M

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering MD:

Copy To:

Specimen(s) Received

1. Lymph-Node: ST9 Inf Pulm Ligament
2. Lymph node: Inf Pulm ligament ST9R
3. Lymph node: Diaphragmatic nodes ST15
4. Lymph node: Subcarinal ST7
5. Lymph node: Common hepatic nodes ST18
6. Soft Tissue: posterior gastric nodule
7. Soft Tissue: anterior gastric nodule
8. Lymph node: para-esophageal ST8
9. Lymph node: para-esophageal ST8L
10. Lymph node: Paracardial nodes ST16
11. Lymph node: ST17
12. Stomach Resection: Proximal stomach and thoracic oesophagus with margin - QS
13. Soft Tissue: Nodule from left triangular ligament

ICD-O-3

Adenocarcinoma NOS 8140/3
Site C64.1
Esophagus, distal third C15.5
perth Gastroesophageal junction C16.D
JW 6/10/13

Other Case Numbers

Diagnosis

1. Lymph-Node: ST9 Inf Pulm Ligament: One lymph node negative for malignancy (0/1).
2. Lymph node: Inf Pulm ligament ST9R: One lymph node negative for malignancy (0/1).
3. Lymph node: Diaphragmatic nodes ST15: Four lymph nodes negative for malignancy (0/4).
4. Lymph node: Subcarinal ST7: Four lymph nodes negative for malignancy (0/4).
5. Lymph node: Common hepatic nodes ST18: Two lymph nodes negative for malignancy (0/2).
- 6,7. Soft Tissue: posterior and anterior gastric nodules: Benign spindle cell lesion consistent with gastrointestinal stromal tumor (GIST) x2. See comment.
8. Lymph node: para-esophageal ST8: Four lymph nodes negative for malignancy (0/4).
9. Lymph node: para-esophageal ST8L: Three lymph nodes negative for malignancy (0/3).
10. Lymph node: Paracardial nodes ST16: Six lymph nodes negative for malignancy (0/6).

[page 2 of 5]
Surgical Pathology Consultation Report

11. Lymph node: ST17: Twenty-four lymph nodes negative for malignancy (0/24).
12. Proximal stomach and thoracic oesophagus, resection: Moderately differentiated adenocarcinoma, gastroesophageal junction, arising in a background of Barrett's esophagus. There is invasion of the lamina propria and the tumor is restricted to the mucosa. Focal changes of low grade and high-grade dysplasia are present. The resection margins are clear of tumor. A small GIST is noted within the muscularis propria.
13. Soft Tissue: Nodule from left triangular ligament: Benign mesothelial cyst

Comment

6,7. The tumor cells of the spindle cell lesions are immunohistochemically reactive with CD117 (cKIT) and SMA and nonreactive with S100.

Synoptic Data

Specimen Type:	Esophagogastrectomy
Tumor Site:	gastroesophageal junction
Tumor Size:	Greatest dimension: 5.0 cm Additional dimensions: 3.0x2.0 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Pathologic Staging (pTNM):	pT1a: Tumor invades lamina propria pN0: No regional lymph node metastasis
Margins:	Proximal margin-Uninvolved by invasive carcinoma Distal margin-Uninvolved by invasive carcinoma Circumferential (Adventitial) margin-Uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 15 mm Margin: Radial
Venous (Large Vessel) Invasion (V):	Absent
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings:	Intestinal metaplasia Dysplasia

Electronically verified by:

Clinical History

ESOPHOGEAL TUMOR

Gross Description

1. The specimen container labeled with the patient's name as "ST9 inf pulm lymph node", contains 1 piece of pink and blackish tissue measuring 2.0 x 0.7 x 0.4 cm. received in 10% buffered formalin.
1A submitted in toto.
2. The specimen container labeled with the patient's name and as "ST9R pulm ligament lymph node", contains one piece of blackish tissue measuring 1.8 x 1.5 x 1.0 cm. received in 10% buffered formalin.
2A bisected and submitted in toto.
3. The specimen container labeled with the patient's name and as "ST15 diaphragmatic lymph node", contains 2 pieces of fibrofatty tissue measuring 1.2 x 1.0 x 0.6 and 2.5 x 1.0 x 0.6 cm. received in 10% buffered formalin.
3A the largest piece bisected and submitted in toto.

[page 3 of 5]
Surgical Pathology Consultation Report

3B the smaller piece bisected and submitted in toto

4. The specimen container labeled with the patient's name and as "ST7 subcarinal lymph node", contains 3 pieces of fibrofatty tissue measuring up to 3 x 2 x 1.5 cm. received in 10% buffered formalin. On sectioning, multiple lymph nodes measuring up to 2.2 cm are retrieved. These lymph nodes are submitted in toto as follows:

4A, 4B the largest lymph node submitted in toto.

4C one lymph node bisected

4D two lymph nodes

5. The specimen container labeled with the patient's name as "ST18 common hepatic lymph node", contains one piece of pink and blackish tissue measuring 1.5 x 1.0 x 0.7 cm. received in 10% buffered formalin.

5A bisected and submitted in toto.

6. The specimen container labeled with the patient's name and as "posterior gastric nodule", contains one piece of white and solid nodule measuring 0.6 x 0.5 x 0.4 cm. received in 10% buffered formalin.

6A bisected and submitted in toto.

7. The specimen container labeled with the patient's name and as "anterior gastric nodule", contains one piece of white and solid nodule measuring 0.7 x 0.4 x 0.3 cm received in 10% buffered formalin.

7A tissue bisected and submitted in toto.

8. The specimen container labeled with the patient's name and as "ST8 para-esophageal lymph node", contains one piece of fibrofatty tissue measuring 2.5 x 2.0 x 1.2 cm. received in 10% buffered formalin.

8A, 8B tissue transected and submitted in toto.

9. The specimen container labeled with the patient's name and as "ST8L para-esophageal lymph node", contains one piece of fibrofatty tissue measuring 4 x 4 x 3 cm. received in 10% buffered formalin. On sectioning, three lymph nodes measuring up to 1.3 cm are retrieved. The lymph nodes are submitted in total as follows:

9A-9C each cassette contains one lymph node bisected

10. The specimen container labeled with the patient's name and as "para-cardial lymph nodes ST16", contains one piece of fibrofatty tissue measuring 5 x 3 x 1 cm. received in 10% buffered formalin. On sectioning, multiple lymph nodes measuring up to 0.6 cm are retrieved.

10A, 10B all the lymph nodes submitted in toto.

11. The specimen container labeled with the patient's name and as "lymph nodes ST17", contains one piece of fibrofatty tissue measuring 6 x 4 x 3 cm. received in 10% buffered formalin. On sectioning, multiple lymph nodes measuring up to 0.6 cm are retrieved. All these lymph nodes submitted in toto as follows:

11A, 11B each cassette contains one lymph node bisected

11C-11F multiple lymph nodes

12. The specimen container labeled with the patient's name and as "stoma resection: Proximal stomach and thoracic esophagus with margin", contains one segment of distal esophagus with proximal stomach en bloc received in 10% buffered formalin. The whole specimen measures 13 cm in longitudinal dimension. The distal esophagus measures 5 cm in longitudinal dimension and the proximal stomach measures 8 cm in maximal longitudinal dimension. Both the esophagus and stomach resection margins are closed by chain staples which were later removed. On the stomach mucosal surface there is one large polypoid tumor measuring 5 cm in maximal dimension. The base of these tumor measures 3 cm in longitudinal dimension and 2 cm in transverse dimension. The distance from this base to the esophagus resection margin is 6.5 cm. From this base to the closest stomach resection margin is 3.5 cm. This base is 1.5 cm below the GE junction. On sectioning, this tumor involves mucosal layer only. Very little fibrofatty tissue is attached on the serosal surface of stomach and esophagus. No lymph node is identified. One section of esophagus proximal resection margin and one section of stomach distal resection margin were examined at intraoperative consultation by frozen section. Representative sections are submitted as follows:

12A proximal resection margin, frozen section resubmitted

12B distal resection margin, frozen section resubmitted

12C one representative resection of esophagus

12D longitudinal section of GE junction with proximal tumor

12E-12I transverse sections of the deepest invasion of tumor, from proximal to distal

12J one representative section of stomach, distal to tumor

[page 4 of 5]
Surgical Pathology Consultation Report

12K peri esophageal fibrofatty tissue submitted in total
12L-12O peri stomach fibrofatty tissue submitted in toto

13. The specimen container labeled with the patient's name and as "nodule from left triangle ligament", contains one cyst measuring 0.5 cm. received in 10% buffered formalin.
13A submitted in toto.

Quick Section Diagnosis

12. A. esophageal resection margin (representative, shave): negative for malignancy (called OR)
12. B. gastric resection margin (representative, shave): negative for malignancy (called OR)

Molecular Diagnostics

Status: Signed Out
Date Reported:

Interpretation

Part 6A

A Val559Asp mutation in exon 11 of the KIT gene is present in this sample using PCR and bi-directional sequencing analysis.

DNA was extracted from paraffin embedded posterior gastric nodule tissue, block 6A, and amplified using primers specific for exons 9, 11, 13 and 17 of the KIT gene, and exons 12 and 18 of the PDGFRA gene.
The PCR products were purified, sequenced and then compared with the reference sequence.

The presence of a p.Val559 Asp mutation in exon 11 of the KIT gene was detected by PCR and sequencing. Two polymorphisms, (p-) and (p-), gene were also identified in this patient.

The mutation detection sensitivity by sequencing is 10-15%.

This analysis is based on our current knowledge of the KIT or PDGFRA activating mutations and their association with GISTs. Demonstration of a mutation in the KIT or PDGFRA gene supports the diagnosis of GIST and predicts response to imatinib. This test was developed and its performance characteristics determined by
It has not been cleared or approved by the U.S.

FDA.

Kim TW, et al. Clinical Cancer Research. 2004; 10: 3076-3081. Heinrich MC, et al. J Clin Oncol. 2003; 21(23): 4342-4349. Heinrich MC, et al. Science 2003; 299:708-710. Chen LL, et al. Curr Oncol Rep. 2005; 7(4): 293-299. Blackstein ME, et al. Can J Gastroenterol. 2006; 20(3):157-163

Part 7A

A Leu576Pro mutation in exon 11 of the KIT gene is present in this sample using PCR and bi-directional sequencing analysis.

DNA was extracted from paraffin embedded anterior gastric nodule tissue, block 7A, and amplified using primers specific for exons 9, 11, 13 and 17 of the KIT gene and exons 12 and 18 of the PDGFRA gene.
The PCR products were purified, sequenced and then compared with the reference sequence.

The presence of a p.Leu576Pro mutation in exon 11 of the KIT gene was detected by PCR and sequencing. Two polymorphisms, (p-) and (p-), gene were also identified in this patient.

The mutation detection sensitivity by sequencing is 10-15%.

[page 5 of 5]
Surgical Pathology Consultation Report

This analysis is based on our current knowledge of the KIT or PDGFRA activating mutations and their association with GISTs. Demonstration of a mutation in the KIT or PDGFRA gene supports the diagnosis of GIST and predicts response to imatinib. This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S.

FDA.

Kim TW, et al. Clinical Cancer Research. 2004; 10: 3076-3081. Heinrich MC, et al. J Clin Oncol. 2003; 21(23): 4342-4349. Heinrich MC, et al. Science 2003; 299:708-710. Chen LL, et al. Curr Oncol Rep. 2005; 7(4): 293-299. Blackstein ME, et al. Can J Gastroenterol. 2006; 20(3):157-163

Block 12E

There is no evidence for the presence of KIT or PDGFRA mutations in this sample using PCR and bi-directional sequencing analysis.

DNA was extracted from paraffin embedded tissue, block 12E, and amplified using primers specific for exons 9, 11, 13 and 17 of the KIT gene and exons 12 and 18 of the PDGFRA gene. The PCR products were purified, sequenced and then compared with the NCBI reference sequence

No mutations were detected in exons 9, 11, 13 and 17 of the KIT gene or exons 12 and 18 of the PDGFRA gene by PCR and sequencing. Two polymorphisms, (p-) and (p-), in exons 12 and 18 of the PDGFRA gene were identified in this sample. Negative results do not rule out the possibility that a mutation may be present in a region not covered by our current testing protocol. PCR and sequencing results might be compromised due to the suboptimal DNA quality of paraffin embedded tissue. Fresh or frozen tissue is recommended whenever possible.

The mutation detection sensitivity by sequencing is 10-15%.

This analysis is based on our current knowledge of the KIT or PDGFRA activating mutations and their association with GISTs. Demonstration of a mutation in the KIT or PDGFRA gene supports the diagnosis of GIST and predicts response to imatinib. This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S.

FDA.

Kim TW, et al. Clinical Cancer Research. 2004; 10: 3076-3081. Heinrich MC, et al. J Clin Oncol. 2003; 21(23): 4342-4349. Heinrich MC, et al. Science 2003; 299:708-710. Chen LL, et al. Curr Oncol Rep. 2005; 7(4): 293-299. Blackstein ME, et al. Can J Gastroenterol. 2006; 20(3):157-163

Source: NCI Genomic Data Commons file 68799792-3591-499a-92ff-0260ec1f2a1e (TCGA-JY-A6FB.EE369447-CEA4-4BFA-AC7B-7783AA09C4CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).